Gene-level copy-number profile of tumor specimen ALCH-AF00-TTP1-A from ALCHEMIST case ALCH-AF00, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.4 years (20,963 days).
Specimen ALCH-AF00-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fd20b952-a512-4bea-acbf-205ea559293b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AF00-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/5e67c59f-724f-4913-aa97-17fb52ced792

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 150; copy number 1: 19,184; copy number 2: 30,325; copy number 3: 8,624; copy number 4: 630; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 99 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,936,859–91,659,972, 34 genes: IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4.
- chr2:91,736,726–91,781,169, 4 genes: AC027612.1, KMT5AP2, AC027612.3, GGT8P.
- chr19:531,760–1,378,431, 61 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:167,916,675–167,937,072, 1 gene, copy number 5 (within-gene range 3–5): MPC2.

Autosomal genes at a single copy (total copy number 1): 16,380. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
